Somatic mutation profile of tumor specimen TCGA-DU-8167-01A (aliquot TCGA-DU-8167-01A-11D-2253-08) from TCGA case TCGA-DU-8167, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 69.2 years (25,262 days).
Specimen TCGA-DU-8167-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08c55f0b-a78e-40bd-9060-5a6164659467.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8167-10A (Blood Derived Normal), aliquot TCGA-DU-8167-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73010ae5-a6ca-4502-b109-64b875bc1768

The open-access MAF lists 59 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 17, Frame Shift Del 3, 3'UTR 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 13/134 reads (10%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 46/126 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 49/106 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; called by muse, mutect2, varscan2
- ADAM30 | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV65562219; called by muse, mutect2, varscan2
- ADGRF5 | c.893T>C p.L298S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.334); catalogued as rs372211867; called by muse, mutect2, varscan2
- ANKMY2 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV61012693; called by muse, mutect2, varscan2
- ANKRD40 | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV53328650; called by muse, mutect2, varscan2
- APOB | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755497502, COSV51951456; called by muse, mutect2, varscan2
- ARFGEF2 | c.1817G>A p.G606D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64214988; called by muse, mutect2, varscan2
- ASB2 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs765782110, COSV60112128; called by muse, mutect2, varscan2
- CEACAM5 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs781851303, COSV55755003; called by muse, mutect2, varscan2
- CEMIP2 | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV65489449; called by muse, mutect2
- CMTM1 | c.454C>T p.P152S (on ENST00000457188 / NM_181269.3; = p.P269S on NM_052999.4) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.871); catalogued as rs1377870237, COSV51749620; called by muse, mutect2, varscan2
- DAD1 | c.26T>G p.I9S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV51663908; called by muse, mutect2, varscan2
- EIF3D | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53401568; called by muse, mutect2
- FBXL17 | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as COSV62861254; called by muse, mutect2
- GNL1 | c.1597C>T p.H533Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV64921449; called by muse, mutect2, varscan2
- HSPG2 | c.10447A>G p.I3483V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65934034; called by muse, mutect2, varscan2
- IL12B | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754181875, COSV51455969; called by muse, mutect2, varscan2
- JCHAIN | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV54660014; called by muse, mutect2, varscan2
- MFSD8 | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1384172728, COSV56552971; called by muse, mutect2
- NRXN3 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.031); catalogued as COSV55358884, COSV99821129; called by muse, mutect2
- NUP155 | c.691A>G p.K231E (on ENST00000231498 / NM_153485.3; = p.K172E on NM_004298.4) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV51534631; called by muse, mutect2, varscan2
- P2RX2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); catalogued as COSV57690236; called by muse, mutect2, varscan2
- PALMD | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV54166841; called by muse, mutect2
- PCARE | c.3839C>T p.A1280V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs771588718, COSV59057928; called by muse, mutect2, varscan2
- PCNX1 | c.2287del p.E763Kfs*52 | Frame Shift Del (DEL) | VAF 18/173 reads (10%) | catalogued as COSV53104534; called by mutect2, pindel, varscan2
- PRKCH | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60652305; called by muse, mutect2, varscan2
- PTER | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54347432; called by muse, mutect2, varscan2
- RGL2 | c.2032A>G p.S678G | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV65842942; called by muse, mutect2, varscan2
- RXRA | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62685457; called by muse, mutect2
- SELENON | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs779808108, COSV100823450, COSV62526266; called by muse, mutect2, varscan2
- SVIL | c.3280G>C p.E1094Q (on ENST00000355867 / NM_021738.3; = p.E668Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV63448060; called by muse, mutect2, varscan2
- TBC1D25 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65123224; called by muse, mutect2, varscan2
- TMPRSS11E | c.749C>A p.T250K | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs748643905, COSV59517686, COSV59521115; called by muse, mutect2, varscan2
- TP53 | c.1146del p.K382Nfs*40 | Frame Shift Del (DEL) | VAF 65/223 reads (29%) | catalogued as CD126191; called by mutect2, pindel, varscan2
- TRPC5 | c.2101-1G>A p.X701_splice | Splice Site (SNP) | VAF 31/159 reads (19%) | catalogued as COSV53302503; called by muse, mutect2, varscan2
- WAS | c.635A>T p.Y212F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.201); catalogued as COSV64997718; called by muse, mutect2
- ZHX1 | c.1493T>C p.M498T | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1206785997, COSV52878952; called by muse, mutect2
- IGHV1OR15-9 | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHROOM4 | c.1487del p.P496Hfs*163 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- ALAS2 | c.1119G>A p.G373= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV58193199; called by muse, mutect2, varscan2
- ARMC6 | c.759C>T p.D253= (on ENST00000392336; = p.D228= on NM_033415.4) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs762938143, COSV54184127; called by muse, mutect2, varscan2
- BANF2 | c.240C>T p.H80= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV55726053; called by muse, mutect2, varscan2
- DUSP29 | c.324C>T p.Y108= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as rs183707898, COSV58301561; called by muse, mutect2, varscan2
- LY6G5C | c.639C>T p.F213= (on ENST00000375863; = p.F138= on NM_025262.3) | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV65498252; called by muse, mutect2, varscan2
- MYOM2 | c.2544C>T p.F848= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs558634230, COSV50732142; called by muse, mutect2, varscan2
- N4BP2L2 | c.2562G>A p.S854= (on ENST00000674422; = p.S425= on NM_033111.4) | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as rs779630327, COSV62635553; called by muse, mutect2, varscan2
- NEK1 | c.1815C>T p.I605= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs375433061, COSV71455105; called by muse, mutect2, varscan2
- NOX5 | c.2235G>A p.L745= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV52995754; called by muse, mutect2
- NPBWR1 | c.420C>T p.A140= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs1445086251, COSV58697645; called by muse, mutect2, varscan2
- OR2G3 | c.537C>T p.C179= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs144392521, COSV60683676; called by muse, mutect2, varscan2
- PLA2R1 | c.2457T>C p.Y819= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV51786331; called by muse, mutect2, varscan2
- RASGRF2 | c.579A>G p.R193= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV54139220; called by muse, mutect2, varscan2
- SLC17A4 | c.1473G>A p.E491= | Silent (SNP) | VAF 61/187 reads (33%) | catalogued as COSV55082142; called by muse, mutect2, varscan2
- TENM1 | c.1440G>A p.Q480= | Silent (SNP) | VAF 4/73 reads (5%) | catalogued as COSV64442365; called by muse, mutect2
- TRPM6 | c.1113G>A p.E371= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs1176651180, COSV62521862; called by muse, mutect2, varscan2
- TTC12 | c.1677G>A p.L559= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV59100053; called by muse, mutect2, varscan2
- TFE3 | c.*337G>A | 3'UTR (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100252777; called by muse, mutect2, varscan2
